Somatic mutation profile of tumor specimen 0D9JN5 from CCDI case PBBIMT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.8 years (6,146 days).
Specimen 0D9JN5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe2a3950-1471-46ef-a434-f4281ac915d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9JN7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b78ae8c-6a1b-403b-b50e-53c21ba15f22

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TTLL12 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767983108, COSV53357944; called by muse, mutect2, varscan2
- FAM122B | c.732C>T p.L244= (on ENST00000370790 / NM_001166599.3; = p.L245= on NM_145284.5) | Silent (SNP) | VAF 95/290 reads (33%) | called by muse, mutect2, varscan2
- CRYGS | c.*5A>G | 3'UTR (SNP) | VAF 14/168 reads (8%) | catalogued as rs1208457588; called by muse, mutect2
